Somatic mutation profile of tumor specimen C3L-04085-01 (aliquot CPT0242520007) from CPTAC case C3L-04085, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 79.3 years (28,971 days).
Specimen C3L-04085-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d661fe10-fa6d-4647-b8cf-aecd0c0bc44a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04085-31 (Blood Derived Normal), aliquot CPT0243440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a643d742-aea0-45eb-b295-ea3d1eb7bca5

The open-access MAF lists 77 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 17, Splice Region 4, Splice Site 3, Nonsense Mutation 2, Intron 2, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1, In Frame Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as rs267606641, CM060802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1_993+3del p.X331_splice | Splice Site (DEL) | VAF 101/157 reads (64%) | hotspot (GDC flag); catalogued as COSV53510033; called by mutect2, pindel, varscan2
- ABCA13 | c.7675T>C p.Y2559H | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV101446857; called by muse, mutect2, varscan2
- ACTN1 | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV51996077, COSV51998313; called by muse, mutect2, varscan2
- AMIGO2 | c.1394G>T p.R465I | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99873500, COSV99873842; called by muse, mutect2, varscan2
- BTBD1 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1161814423; called by muse, mutect2, varscan2
- CCDC168 | c.21098G>A p.R7033H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59421563; called by muse, mutect2, varscan2
- CNTN5 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749499011; called by muse, mutect2, varscan2
- COMP | c.601C>A p.R201= | Splice Region (SNP) | VAF 188/350 reads (54%) | catalogued as rs776283041, COSV55876492; called by muse, mutect2, varscan2
- FCHO1 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 74/422 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs371005650; called by muse, mutect2, varscan2
- FLG | c.5341C>T p.R1781C | Missense Mutation (SNP) | VAF 134/643 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs201021216, COSV64239624; called by muse, mutect2, varscan2
- GP6 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 77/496 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs771474578; called by muse, mutect2, varscan2
- JPH2 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 206/681 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs748370653, COSV104426161; called by muse, mutect2, varscan2
- LSM14B | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1335827345; called by muse, mutect2, varscan2
- MMP8 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as rs776582589; called by muse, mutect2, varscan2
- PITPNM1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs754527358; called by muse, mutect2
- PTEN | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 121/194 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64292105, COSV64302293; called by muse, mutect2, varscan2
- RAB27A | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 142/387 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs201697259; called by muse, mutect2, varscan2
- RBM5 | c.1840-8G>A | Splice Region (SNP) | VAF 110/268 reads (41%) | catalogued as rs1279127981; called by muse, mutect2, varscan2
- SCFD1 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated, low confidence (0.1); catalogued as rs866183796; called by mutect2, varscan2
- SESN1 | c.709T>C p.S237P (on ENST00000356644 / NM_001199933.1; = p.S296P on NM_014454.3) | Missense Mutation (SNP) | VAF 129/351 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1467217774; called by muse, mutect2, varscan2
- SH2B1 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs766274908, COSV59463379; called by muse, mutect2, varscan2
- SORL1 | c.4325G>A p.R1442Q | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs771609208; called by muse, mutect2, varscan2
- STAP1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs781246980, COSV55330834; called by muse, mutect2, varscan2
- STX3 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 121/349 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs199896680; called by muse, mutect2, varscan2
- THSD7B | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs200250890, COSV55707540; called by muse, mutect2, varscan2
- TPM1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 124/360 reads (34%) | catalogued as rs1005672618; called by muse, mutect2, varscan2
- WDR97 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 214/591 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1409234831; called by muse, mutect2, varscan2
- XYLT1 | c.2725T>G p.L909V | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs1425514977; called by muse, mutect2, varscan2
- ZHX2 | c.1565A>G p.Y522C | Missense Mutation (SNP) | VAF 102/237 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.707); catalogued as rs750857053; called by muse, mutect2, varscan2
- ZNF597 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1311861208; called by muse, mutect2, varscan2
- ADAMTS20 | c.1461G>C p.K487N | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ALX1 | c.228G>A p.V76= | Splice Region (SNP) | VAF 76/183 reads (42%) | called by muse, mutect2, varscan2
- ANKEF1 | c.1304T>C p.I435T | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- BTN3A1 | c.947G>T p.S316I | Missense Mutation (SNP) | VAF 145/390 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- BUB1 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CCDC18 | c.4108del p.S1370Lfs*8 | Frame Shift Del (DEL) | VAF 98/229 reads (43%) | called by mutect2, pindel, varscan2
- DPY19L3 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSAP | c.2474-5del | Splice Region (DEL) | VAF 58/174 reads (33%) | called by mutect2, pindel, varscan2
- HECW2 | c.4559C>T p.P1520L | Missense Mutation (SNP) | VAF 99/295 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED26 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO15B | c.5560T>C p.F1854L | Missense Mutation (SNP) | VAF 176/411 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NT5E | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 140/412 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- OR5M10 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 230/609 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PADI3 | c.1559A>C p.D520A | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLQ | c.2356dup p.T786Nfs*10 | Frame Shift Ins (INS) | VAF 87/282 reads (31%) | called by mutect2, pindel, varscan2
- PTPRM | c.2161A>G p.T721A | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RECQL5 | c.1448+1G>T p.X483_splice | Splice Site (SNP) | VAF 114/249 reads (46%) | called by muse, mutect2, varscan2
- SCRIB | c.2152_2163dup p.E718_R721dup | In Frame Ins (INS) | VAF 84/280 reads (30%) | called by mutect2, varscan2
- SIRPB1 | c.730A>C p.N244H | Missense Mutation (SNP) | VAF 33/434 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2
- SPATA21 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SSTR1 | c.655T>C p.W219R | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2*
- TDRD15 | c.4933T>A p.F1645I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- YWHAE | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ALDH1L2 | c.225G>A p.V75= | Silent (SNP) | VAF 134/278 reads (48%) | called by muse, mutect2, varscan2
- BBS12 | c.1197C>T p.H399= | Silent (SNP) | VAF 161/348 reads (46%) | catalogued as rs764483162; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC33 | c.2013C>T p.S671= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV51431077; called by muse, mutect2, varscan2
- KCNB2 | c.1866G>A p.P622= | Silent (SNP) | VAF 87/277 reads (31%) | catalogued as rs143631623; called by muse, mutect2, varscan2
- MTMR9 | c.618C>A p.L206= | Silent (SNP) | VAF 128/288 reads (44%) | catalogued as COSV55313802; called by muse, mutect2, varscan2
- PACC1 | c.66G>A p.E22= | Silent (SNP) | VAF 44/299 reads (15%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.645C>T p.D215= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs201251164, COSV100982358, COSV65047104; called by muse, mutect2, varscan2
- RAB8B | c.420A>G p.A140= | Silent (SNP) | VAF 66/151 reads (44%) | called by muse, mutect2, varscan2
- SGPP2 | c.237C>T p.Y79= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as rs182912853; called by muse, mutect2, varscan2
- ST3GAL6 | c.801G>A p.A267= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs759540737, COSV54581696; called by muse, mutect2, varscan2
- THEMIS2 | c.942C>T p.F314= | Silent (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- TNXB | c.11643G>A p.G3881= (on ENST00000647633; = p.G3634= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 173/766 reads (23%) | called by muse, mutect2, varscan2
- TTLL7 | c.636G>A p.S212= | Silent (SNP) | VAF 92/179 reads (51%) | catalogued as rs764286113, COSV53084126; called by muse, mutect2, varscan2
- WASH6P | c.936G>A p.G312= | Silent (SNP) | VAF 54/152 reads (36%) | called by mutect2, varscan2
- ZCRB1 | c.42A>T p.V14= | Silent (SNP) | VAF 99/216 reads (46%) | catalogued as COSV99861269; called by muse, mutect2, varscan2
- ZNF668 | c.234G>A p.A78= | Silent (SNP) | VAF 13/300 reads (4%) | called by muse, mutect2
- ZNF735 | c.288C>T p.D96= | Silent (SNP) | VAF 18/287 reads (6%) | called by muse, mutect2
- AC024651.2 | chr15:97874010 C>A | 5'Flank (SNP) | VAF 51/156 reads (33%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099204 C>T | 3'Flank (SNP) | VAF 30/216 reads (14%) | called by muse, varscan2
- NLGN4Y | c.625+25461_625+25466del | Intron (DEL) | VAF 34/51 reads (67%) | called by mutect2, pindel, varscan2
- PROP1 | c.*23T>C | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- RSPRY1 | c.351-394_351-391del | Intron (DEL) | VAF 74/257 reads (29%) | called by mutect2, pindel, varscan2
